Somatic mutation profile of tumor specimen TARGET-20-PAPUNR-09A (aliquot TARGET-20-PAPUNR-09A-01D) from TARGET case TARGET-20-PAPUNR, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.3 years (4,846 days).
Specimen TARGET-20-PAPUNR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d34de583-4c0d-48a1-a924-4a4b97c88796.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAPUNR-14A (Bone Marrow Normal), aliquot TARGET-20-PAPUNR-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/febf3589-c247-4f3f-8e62-44417f3ea173

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 12/124 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, varscan2
- CBL | c.1097A>T p.E366V | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FLT4 | c.3100A>G p.I1034V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
